Somatic mutation profile of tumor specimen MP2PRT-PATMUK-TMP1-A (aliquot MP2PRT-PATMUK-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATMUK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,048 days).
Specimen MP2PRT-PATMUK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd41c85a-2651-4abb-bf16-b18a0ff823fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATMUK-NM1-B (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATMUK-NM1-B-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2ebb0b6-7779-4b10-93e6-7413e600669b

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP002512.3 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs780409038, COSV99687990; called by muse, mutect2, varscan2
- CPO | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs144914072; called by muse, mutect2, varscan2
- GIPC3 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 99/362 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as rs766991127, COSV59259041; called by muse, mutect2, varscan2
- HMCN2 | c.14110C>T p.R4704W | Missense Mutation (SNP) | VAF 160/424 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs750732009; called by muse, mutect2, varscan2
- HYDIN | c.6568C>T p.R2190C | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV59267635; called by muse, mutect2, varscan2
- KRT8 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs147928805; called by muse, mutect2, varscan2
- MARCO | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs772912755, COSV59054371; called by muse, mutect2, varscan2
- MYH7 | c.4823G>A p.R1608H | Missense Mutation (SNP) | VAF 147/546 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs587779391, CM127954, COSV62521586; called by muse, mutect2, varscan2
- OR10G8 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1330444806; called by muse, mutect2, varscan2
- RNF213 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.418); catalogued as rs760116718; called by muse, mutect2, varscan2
- SRGAP1 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs115771292; called by muse, mutect2, varscan2
- TEX11 | c.1189G>C p.E397Q (on ENST00000344304; = p.E382Q on NM_031276.3) | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV100722289; called by muse, mutect2, varscan2
- TTN | c.96589G>C p.E32197Q (on ENST00000591111; = p.E24773Q on NM_003319.4) | Missense Mutation (SNP) | VAF 81/291 reads (28%) | PolyPhen probably damaging (0.998); catalogued as COSV60049660; called by muse, mutect2, varscan2
- VRTN | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 184/660 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769734289, COSV56439380, COSV56439622; called by muse, mutect2, varscan2
- ASXL2 | c.1253_1254insGGGGGGCACC p.L419Gfs*17 | Frame Shift Ins (INS) | VAF 69/260 reads (27%) | called by mutect2, pindel, varscan2
- CHD1L | c.1362G>C p.R454S | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005629 TCA>CTGAAC | Missense Mutation (INS) | VAF 50/104 reads (48%) | called by pindel, varscan2*
- KIF1A | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 9/273 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLE2 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 34/245 reads (14%) | called by muse, mutect2, varscan2
- PSMG2 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SEMA3E | c.1487T>G p.I496S | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- TRGV9 | c.366delinsTCTCCCCCCTTCT | In Frame Ins (INS) | VAF 78/187 reads (42%) | called by mutect2*, pindel, varscan2*
- ZSWIM8 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 125/368 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ARHGEF10 | c.2841C>A p.V947= (on ENST00000398564; = p.V922= on NM_014629.4) | Silent (SNP) | VAF 111/468 reads (24%) | catalogued as rs373417964; called by muse, mutect2, varscan2
- FLG | c.285G>A p.P95= | Silent (SNP) | VAF 143/284 reads (50%) | catalogued as rs768672802; called by muse, mutect2, varscan2
- FMN1 | c.2490C>G p.P830= (on ENST00000616417 / NM_001277313.2; = p.P607= on NM_001103184.4) | Silent (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- HPS3 | c.111G>C p.A37= | Silent (SNP) | VAF 172/585 reads (29%) | called by muse, mutect2, varscan2
- INSC | c.903G>A p.A301= | Silent (SNP) | VAF 95/331 reads (29%) | catalogued as rs758254925; called by muse, mutect2, varscan2
- KCNV1 | c.390G>A p.A130= | Silent (SNP) | VAF 155/574 reads (27%) | catalogued as rs148889439; called by muse, mutect2, varscan2
- RPS6KL1 | c.237C>T p.G79= | Silent (SNP) | VAF 73/330 reads (22%) | catalogued as rs762131303, COSV100664988; called by muse, mutect2, varscan2
- SREBF1 | c.2745G>A p.L915= | Silent (SNP) | VAF 76/127 reads (60%) | called by muse, mutect2, varscan2
- TOP2A | c.3351C>T p.S1117= | Silent (SNP) | VAF 92/459 reads (20%) | catalogued as rs770546190, COSV70732053, COSV70732805; called by muse, mutect2, varscan2
